Gene-level copy-number profile of tumor specimen TCGA-AG-A025-01A from TCGA case TCGA-AG-A025, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 62.8 years (22,952 days).
Specimen TCGA-AG-A025-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.24817088-83a6-4665-bf7f-f871566afa09.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A025-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7b1c3988-541d-41cd-a2aa-5ee39439467c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 189; copy number 2: 57,961; copy number 3: 1,630.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-A025-01A-01D-A008-01): tumor purity 0.77, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,771,296–7,781,432, 2 genes (within-gene range 0–2): VAMP3, Z98884.2.
- chr3:36,616,006–36,637,457, 1 gene (within-gene range 0–2): NBPF21P.
- chr3:71,675,414–71,786,425, 4 genes (within-gene range 0–2): EIF4E3, GPR27, PROK2, AC096970.1.
- chr4:76,894,152–76,898,144, 1 gene: SOWAHB.
- chr4:186,189,032–186,191,490, 1 gene: FLJ38576.
- chr9:111,631,334–111,670,229, 3 genes: DNAJC25, DNAJC25-GNG10, GNG10.
- chr11:32,435,738–32,440,383, 6 genes: AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4.
- chr12:101,696,002–101,696,450, 1 gene: AC010205.1.
- chr14:95,516,136–95,544,724, 4 genes: AL133467.1, SNHG10, SCARNA13, GLRX5.
- chr17:36,722,443–36,726,346, 1 gene (within-gene range 0–2): AC243830.1.
- chr20:646,615–675,802, 3 genes: SRXN1, AL121758.1, SCRT2.
- chr20:23,030,863–23,039,241, 2 genes: AL049651.2, SSTR4.
- chr22:42,269,703–42,279,534, 1 gene: OGFRP1.
- chr22:46,039,907–46,113,928, 7 genes (within-gene range 0–2): LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2.
- chr22:46,255,663–46,263,343, 1 gene: PKDREJ.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 183. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
